Gene-level copy-number profile of tumor specimen MP2PRT-PAWCIU-TMP1-A from MP2PRT case MP2PRT-PAWCIU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,445 days).
Specimen MP2PRT-PAWCIU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ce21e643-e90c-463d-88e5-b8048740c5f0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAWCIU-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/de1b2391-af95-4472-b086-d575c76364da

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 536; copy number 2: 34,121; copy number 3: 20,357; copy number 4: 3,847; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr2:88,857,161–89,245,596, 35 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV3-25, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr7:38,335,041–38,340,998, 2 genes (within-gene range 0–1): TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene (within-gene range 0–3): TRGV5P.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–3): TRDD1, TRDD2, TRDD3, TRDJ1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:170,736,173–170,737,777, 1 gene, copy number 6: AL731684.1.

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
